Gene-level copy-number profile of tumor specimen TCGA-W3-A825-06A from TCGA case TCGA-W3-A825, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 65.0 years (23,741 days).
Specimen TCGA-W3-A825-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.aa35d346-a844-4ce9-9409-2b079260da65.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-W3-A825-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/92f65cce-5c18-42f4-bf7b-53f2b7c36dde

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 666; copy number 2: 15,569; copy number 3: 20,388; copy number 4: 13,367; copy number 5: 5,689; copy number 6: 3,911; copy number 7: 1; copy number 11: 23; copy number 14: 5; copy number 15: 12; copy number 18: 6; copy number 19: 6; copy number 21: 16; copy number 22: 32; copy number 23: 12; copy number 24: 21; copy number 28: 35; copy number 31: 9; copy number 32: 49.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-W3-A825-06A-11D-A34T-01): tumor purity 0.69, ploidy 3.09, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 227 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:207,240,122–207,309,292, 1 gene, copy number 7 (within-gene range 5–7): AL596218.1.
- chr4:110,251,871–112,442,621, 32 genes, copy number 22 (within-gene range 22–24): HSBP1P2, RNF14P2, RNU6-205P, ZBED1P1, ENPEP, RPL7L1P13, ZNF969P, AC093872.1, AC098798.1, PANCR, PITX2, LINC01438, MIR297, LYPLA1P2, AC004062.1, RNU6-289P, AC083795.1, AC083795.2, AC139718.2, AC139718.1, AC004704.1, CCDC34P1, TUBB8P3, AC093663.1, FAM241A, AC093663.2, AC109347.1, AP1AR, AC109347.2, TIFA, ALPK1, RTEL1P1.
- chr4:119,799,089–120,650,796, 10 genes, copy number 15–23: LINC01365, AC097173.1, LINC02502, Y_RNA, AC097173.2, MAD2L1, AC073475.1, LTV1P1, SAR1AP3, AC025741.1.
- chr4:127,094,410–127,844,040, 11 genes, copy number 23 (within-gene range 2–23): AC093772.1, AC093772.2, AC097462.1, AC097462.2, AC097462.3, INTU, SLC25A31, HSPA4L, AC093591.3, AC093591.1, AC093591.2.
- chr4:129,299,175–131,975,952, 21 genes, copy number 24: AC082650.1, AC082650.2, LINC02466, LINC02465, EEF1GP8, LINC02479, PGBD4P4, GAPDHP56, AC093831.2, AC093831.1, AC093902.1, AC025554.1, RNU6-224P, LINC02377, AC105424.1, RN7SL205P, SNHG27, SNORA70, AC107393.1, RPL7AP28, AC096711.2.
- chr4:139,411,927–140,154,184, 16 genes, copy number 21: AC097376.3, AC097376.2, AC097376.1, RAB33B, SETD7, FTH1P24, AC112236.2, AC112236.3, AC112236.1, MGST2, RN7SKP237, H3P16, MAML3, AC108053.1, RN7SKP253, AC131182.1.
- chr4:153,710,160–156,692,636, 55 genes, copy number 19–32: RNF175, AC020703.1, SFRP2, AC079298.3, DCHS2, AC079298.1, AC079298.2, AC110775.1, AC110753.1, PLRG1, RNU6-1285P, AC107385.1, FGB, FGA, FGG, AC107385.2, LRAT, NDUFB2P1, AC009567.1, AC009567.2, RBM46, RNU2-66P, RNU2-44P, AC097467.3, AC104407.1, NPY2R, AC097467.1, MAP9, YWHAEP4, AC097467.2, AC097467.4, AC097526.1, MTCYBP17, MTND6P17, MTND5P9, MTND4P8, MTND3P3, MTCO3P9, MTATP6P9, MTCO2P9, MTCO1P9, MTND2P33, MTND1P22, AC107208.1, GUCY1A1, AC104083.1, GUCY1B1, ASIC5, TDO2, CTSO, FTH1P21, AC096736.3, LINC02272, AC096736.2, AC096736.1.
- chr4:158,769,026–158,908,050, 1 gene, copy number 31 (within-gene range 2–31): FNIP2.
- chr4:158,893,134–163,520,539, 31 genes, copy number 14–31: C4orf45, SNORD39, PSME2P3, FABP5P12, Y_RNA, RAPGEF2, MIR3688-1, MIR3688-2, AC074344.1, AC074344.2, LINC02233, AC093853.1, LINC02477, RPS14P7, AC104793.1, FSTL5, AC023136.1, MTHFD2P4, TOMM22P4, AC021134.1, AC021134.2, AC084752.1, MIR4454, AC022272.1, NAF1, AC079238.1, NPY1R, NPY5R, RPL35AP12, TKTL2, TMA16.
- chr4:163,529,771–163,530,697, 1 gene, copy number 28: AC093788.1.
- chr4:168,828,919–170,033,031, 22 genes, copy number 28: AC080188.1, AC080188.2, CBR4, RNU6-853P, RNY4P17, AC021151.1, SH3RF1, RPL6P12, AC096741.1, NEK1, AC084724.1, CLCN3, HPF1, PTGES3P3, AC079768.1, AC079768.3, AC079768.4, LINC02275, AC079768.2, AC084866.2, AC084866.1, MFAP3L.
- chr4:179,389,134–180,059,792, 3 genes, copy number 15 (within-gene range 2–15): AC020551.1, AC021193.1, AC108169.1.
- chr4:189,764,391–190,092,279, 23 genes, copy number 11 (within-gene range 2–11): FRG1-DT, LINC01596, FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.

Autosomal genes at a single copy (total copy number 1): 666. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
